Somatic mutation profile of tumor specimen TCGA-FY-A3YR-01A (aliquot TCGA-FY-A3YR-01A-11D-A22Z-08) from TCGA case TCGA-FY-A3YR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 64.1 years (23,395 days).
Specimen TCGA-FY-A3YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4cc0df3-b9c4-49e1-9b6a-b78beaa0756a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3YR-10A (Blood Derived Normal), aliquot TCGA-FY-A3YR-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b62c58b2-c56a-4a0a-9443-095758bd4db7

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARFIP2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs771258941, COSV99601442; called by muse, mutect2, varscan2
- COL6A6 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs961891229, COSV100650729; called by muse, mutect2, varscan2
- CPT1A | c.1503T>G p.D501E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV99681493; called by muse, mutect2, varscan2
- DEGS1 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083433; called by muse, mutect2
- GRHL3 | c.1256A>G p.K419R (on ENST00000350501 / NM_198174.3; = p.K424R on NM_021180.3) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.963); catalogued as COSV99359589; called by muse, mutect2, varscan2
- MYO18B | c.6749T>A p.L2250H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124613, COSV100124715; called by muse, mutect2, varscan2
- PGBD5 | c.472C>G p.H158D (on ENST00000525115; = p.H227D on NM_001258311.2) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0.138); catalogued as COSV100358785; called by muse, mutect2, varscan2
- RC3H1 | c.1586G>A p.S529N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99281644; called by muse, varscan2
- TRHDE | c.1940T>C p.V647A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99670833, COSV99671913; called by muse, mutect2, varscan2
- ZNF343 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99601577; called by muse, mutect2, varscan2
- PDZD2 | c.3424_3427del p.T1142* | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by pindel, varscan2
- FLG | c.2736T>A p.R912= | Silent (SNP) | VAF 12/395 reads (3%) | catalogued as rs1431415013, COSV100911926; called by muse, mutect2
- QTRT2 | c.1117C>T p.L373= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs1213270281, COSV99847000; called by muse, mutect2
- STT3A | c.171C>G p.T57= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV101205091, COSV101205263; called by muse, mutect2, varscan2
